Gene-level copy-number profile of tumor specimen TCGA-CN-A641-01A from TCGA case TCGA-CN-A641, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 47.8 years (17,454 days).
Specimen TCGA-CN-A641-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.15043d6b-83f2-46b2-ad20-cc92d21adacb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-A641-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cce37af9-3ea4-4aed-9ca3-e87c9a73a4d1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 8; copy number 2: 10,577; copy number 3: 6,827; copy number 4: 34,351; copy number 5: 1,328; copy number 6: 4,653; copy number 7: 866; copy number 8: 827; copy number 9: 73; copy number 10: 109; copy number 14: 70; copy number 15: 101; copy number 16: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-A641-01A-11D-A30D-01): tumor purity 0.67, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:56,887,107–57,299,281, 5 genes (within-gene range 0–2): AC010999.2, AC010999.1, TCF12, HNRNPA3P11, SNORD13D.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 364 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:151,336,843–155,761,217, 66 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr18:21,817,624–21,893,996, 7 genes, copy number 9: SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P.
- chr18:22,130,603–24,162,211, 42 genes, copy number 10: RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3.
- chr18:24,170,505–24,218,404, 3 genes, copy number 10: RNA5SP452, Metazoa_SRP, RNU6-435P.
- chr18:25,818,234–26,391,685, 12 genes, copy number 15 (within-gene range 8–15): RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P.
- chr19:9,324,174–10,869,790, 89 genes, copy number 15 (within-gene range 2–15) (broad region; genes not listed).
- chr19:14,840,466–15,950,350, 64 genes, copy number 10 (broad region; genes not listed).
- chr19:27,638,483–31,787,255, 81 genes, copy number 14–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
